Gene-level copy-number profile of specimen HCM-CSHL-0773-C50-85N from HCMI case HCM-CSHL-0773-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 62.3 years (22,742 days).
Specimen HCM-CSHL-0773-C50-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5dbea5bf-c964-40eb-9117-c6b599d42d43.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0773-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/7209cb15-0225-4e5a-b9fc-e6e29ec9fd6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,419; copy number 2: 32,471; copy number 3: 7,100; copy number 4: 339; copy number 5: 4; copy number 6: 18; copy number 7: 3; copy number 8: 16; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:132,963,732–132,963,793, 1 gene, copy number 5: RNU7-21P.
- chr21:15,928,296–16,645,467, 1 gene, copy number 6 (within-gene range 4–6): MIR99AHG.
- chr21:16,094,415–16,590,325, 11 genes, copy number 5–6: VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2.
- chr21:44,012,309–44,495,519, 32 genes, copy number 6–9: TRAPPC10, H2AZP1, PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1, AIRE, PFKL, AP001062.3, CFAP410, AP001062.1, AP001062.2, AP001063.1, TRPM2, TRPM2-AS, AP001065.2, AP001065.1, LRRC3-DT, LRRC3, MTCYBP21, MTND6P21, MTND5P1, AP001065.3, LINC02575, AP001065.4.
- chr21:44,579,455–44,580,604, 1 gene, copy number 7 (within-gene range 4–7): KRTAP10-5.

Autosomal genes at a single copy (total copy number 1): 18,411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
